MMRF case MMRF_1470 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/96e4342b-4541-4dbd-9389-7be5a2c3ceb5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.7 years (25,834 days); ISS stage: II; Days to last known disease status: 964 days (2.6 years); Days to last follow up: 964 days (2.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 27 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 5 days; Days to treatment end: 59 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 60 days; Days to treatment end: 199 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 185 days; Days to treatment end: 213 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 200 days; Days to treatment end: 611 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 291 days; Days to treatment end: 607 days (1.7 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 964.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 3): M Protein 3.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 421 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.11 mg/dL; Immunoglobulin G 46.8 g/L; Immunoglobulin A 0.154 g/L; Immunoglobulin M 0.095 g/L; Beta 2 Microglobulin 3.1 µg/mL; Hemoglobin 5.64 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 367 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 27 g/L; Total Protein 9.5 g/dL; Glucose 5.01 mmol/L.
- Day 95 (ECOG 1): Immunoglobulin G 15.6 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.15 ×10⁹/L; Platelets 412 ×10⁹/L; Creatinine 46 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 6.8 g/dL; Glucose 5.23 mmol/L.
- Day 172 (ECOG 1): Hemoglobin 8.62 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 5.45 mmol/L.
- Day 291 (ECOG 1): Hemoglobin 8.56 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.36 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 45.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 4.73 mmol/L.
- Day 347 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 6.48 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 3.64 ×10⁹/L; Platelets 274 ×10⁹/L; Creatinine 45.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 6.2 g/dL; Glucose 4.73 mmol/L.
- Day 437 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Hemoglobin 8.31 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.74 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 41.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 5.01 mmol/L.
- Day 536 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 5.96 g/L; Immunoglobulin A 0.368 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.85 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.62 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 35 g/L; Total Protein 6.1 g/dL; Glucose 4.62 mmol/L.
- Day 634 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 7.74 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.49 ×10⁹/L; Platelets 337 ×10⁹/L; Creatinine 38 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.45 mmol/L; Albumin 34 g/L; Total Protein 6.3 g/dL; Glucose 4.4 mmol/L.
- Day 725 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.1 mg/dL; Hemoglobin 8.49 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 281 ×10⁹/L; Creatinine 35.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 5.12 mmol/L.
- Day 810 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.96 mg/dL; Immunoglobulin G 8.22 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 4.46 mmol/L.
- Day 894 (ECOG 1): Hemoglobin 8.74 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 319 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 7.4 g/dL; Glucose 4.73 mmol/L.

Other clinical attributes
- Day -2: Weight: 51 kg; Height: 147 cm.

Family history
- Relative with cancer history: no.

Biospecimens (1 sample)
- Sample MMRF_1470_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
